Surgical pathology report (de-identified scan), TCGA case TCGA-X6-A7W8, project TCGA-SARC (Sarcoma), tissue source site University of Iowa, specimen TCGA-X6-A7W8-01A (Primary Tumor).

[page 1 of 2]
--SURGICAL PATHOLOGY CONSULTATION--

Status: Final result

Results

Collection Information

Specimen#	Collection Date	Collection Time	Collected By	Specimen Source	Specimen Description
-----------	-----------------	-----------------	--------------	-----------------	----------------------

Component Results

Component

DIAGNOSIS

Soft tissue, right thigh, resection:
High grade pleomorphic myxofibrosarcoma, 17.5 cm in greatest dimension.
Surgical margins: 0.1 cm from the proximal margin, 0.1 cm from the deep margin, 0.6 cm from the anterior margin, 0.9 cm from the posterior margin, present at the distal margin.
Perineural invasion identified.
Lymph node, proximal end, excision:
One of two lymph nodes involved by metastatic sarcoma with extracapsular extension (1/2).

Comment:

Date reported: Pathologist (Electronic Signature)

HISTORY

Stitch proximal end.

TISSUE SUBMITTED

A. Right thigh mass (stitch proximal end)

GROSS

Specimen condition: Received in saline in a container labeled with the patient's name, hospital number and "right thigh mass (stitch proximal end)" is soft tissue mass with overlying skin.
Type of procedure: Resection.
Overall size: 19 x 10.5 x 9.0 cm.
Types of identifiable tissue present and size of each: A 22 x 3.5 cm tan-white unremarkable skin is present at one aspect. The external surface is smooth to lobulated with attached skeletal muscle and fibroadipose tissue.
Orientation: The specimen is oriented with a surgical stitch at the proximal end and further orientation is provided by for anterior, posterior and deep aspects.
Tumor gross morphologic description: Sectioning reveals an ovoid, red-yellow-white, mass that appears encapsulated. The mass is mostly composed of yellow lobulated myxoid material (70% of total surface) with a focal area of dark red friable, possibly hemorrhagic area in the center. In addition to the myxoid area, an area of tan-white lobulated, firm and fleshy tissue is present (30% of the total surface; 6.5 x 4.2 x 3.7 cm). Involvement/invasion of major structures: Presence of satellite nodules away from main mass: A 1.0 x 0.6 x 0.5 cm white well defined firm nodule is present within skeletal muscle, 0.8 cm to the main mass. Lymph nodes, if present: Two white yellow firm possible lymph nodes/satellite nodules are present on proximal end, 2.7 and 1.5 cm in greatest dimension.
Margins: Grossly the mass is 0.1 cm to the distal and deep margins, 0.2 cm to proximal, 0.5 cm to posterior, 0.8 cm to anterior aspect.
Inking by pathologist: Proximal end = blue, distal end = green, deep = black, anterior and posterior = orange.
Tissue saved for special studies: None.
Blocks submitted: A1-A4, the mass to include solid area; A5, the nodule within muscle; A6-A8, mass from myxoid area; A9, proximal and distal margins; A10, deep and anterior margin; A11, posterior margin and one possible lymph node from proximal end, representatively; A12, the other possible lymph node from proximal end, representatively.

MICROSCOPIC

Tumor microscopic description: Sections show a neoplasm composed of markedly pleomorphic cells with enlarged nuclei and atypical mitotic figures. Focal areas show a slightly fascicular growth pattern and myxoid stroma. Focal cells show multinucleation. Areas of necrosis are present.
Histologic type: Pleomorphic myxofibrosarcoma.
Histologic grade: High grade.
Mitotic rate (per 10 hpf @ 40X): 40/hpf.
Extent of necrosis: Approximately 30% on limited sampling.
Vascular invasion: Not identified.
Perineural invasion: Present.
Inflammatory infiltrate: Present.
Maximal dimension: 17.5 cm (gross examination).
Minimal distance(s) to resection margins: The mass measures 0.1 cm from the proximal margin, 0.1 cm from the deep margin, 0.6 cm from the anterior margin, 0.9 cm from the posterior margin and involves the distal margin.

ICD-O-3

Fibromyxosarcoma 8811/3

Site thigh NOS C49.2

9/10/10/13

[page 2 of 2]
Evidence of pre-existing benign lesion: None.
Lymph nodes: Two lymph nodes are identified with metastatic tumor
effacing one lymph node with extracapsular extension.
Special studies: None.

DEFINITIONS

Pathologic Primary Tumor (T)
X T2 Tumor more than 5 cm in greatest dimension
Regional Lymph Nodes (N)
XX N1 Regional lymph node metastasis

The pathologic stage based on available pathologic material is: T2 N1
Performed by:

As the primary pathologist on this case, I have personally reviewed this
case and edited the report as necessary.

INTERNAL CONSULTATION

Reviewed with

Patient Release Status:

This result is not viewable by the patient.

Lab and Collection

--SURGICAL PATHOLOGY CONSULTATION--

- Lab and Collection Information

Result History

--SURGICAL PATHOLOGY CONSULTATION--

- Order Result History Report

Result Entered By

Lab Information

Source: NCI Genomic Data Commons file 0d92924c-6271-4ed6-aad3-a895c071d2a4 (TCGA-X6-A7W8.4626A3B4-9609-4AEB-BDD2-CC05AEE8C342.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).